Somatic mutation profile of tumor specimen TCGA-BG-A2L7-01A (aliquot TCGA-BG-A2L7-01A-11D-A18P-09) from TCGA case TCGA-BG-A2L7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 68.7 years (25,091 days).
Specimen TCGA-BG-A2L7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f6c79ba-5804-46ca-92ac-04bf6785e3b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A2L7-10A (Blood Derived Normal), aliquot TCGA-BG-A2L7-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45a6e2f8-55ea-4a44-81d9-6af3ae9f5671

The open-access MAF lists 718 somatic variants for this specimen: 562 protein-altering or splice-affecting, 142 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 335, Frame Shift Del 166, Silent 142, Nonsense Mutation 22, Frame Shift Ins 22, Splice Site 9, Intron 8, In Frame Del 5, RNA 3, Splice Region 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.668del p.K223Rfs*11 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | catalogued as rs80357537, CD057384, CS1211735; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CEP290 | c.1666del p.I556Ffs*17 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs727503855, CD073590; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- FAH | c.615del p.F205Lfs*2 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs1057517084; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 24/75 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 27/65 reads (42%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GALK1 | c.410del p.G137Vfs*27 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | catalogued as rs767329054, CD993840; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ITGB4 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs121912462, CM981090, COSV52322436; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- RAD50 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370769989, COSV54748170; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RHOA | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 31/73 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV69042564; called by muse, mutect2, varscan2
- A1BG | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs895194706, COSV54054069; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCA1 | c.948del p.L317* | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | catalogued as COSV66069850; called by mutect2, pindel, varscan2
- ABCA12 | c.4544G>A p.R1515Q (on ENST00000272895 / NM_173076.3; = p.R1197Q on NM_015657.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs774279263, CM1311790, COSV55948366; called by muse, mutect2, varscan2
- ABTB2 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs371505033; called by muse, mutect2, varscan2
- ADAM11 | c.1769A>G p.Q590R | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1252041870, COSV99567799; called by muse, mutect2, varscan2
- AFAP1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.941); catalogued as rs1413774312, COSV100632102; called by muse, mutect2, varscan2
- AFF1 | c.2968A>G p.K990E | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV100321028; called by muse, mutect2, varscan2
- AGO1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100940920; called by muse, mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 20/44 reads (45%) | catalogued as rs748399150; called by mutect2, varscan2
- AIPL1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs1284009768, CM167090, COSV100006183, COSV51506645, COSV51506697; called by muse, mutect2, varscan2
- AKAP6 | c.31del p.L11* | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs771895850; called by mutect2, pindel, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs186732768, COSV99541374; called by muse, mutect2, varscan2
- AKR1C1 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV101080564; called by muse, varscan2
- ALMS1 | c.8888C>T p.P2963L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); catalogued as COSV52501715; called by muse, mutect2, varscan2
- ALOX15B | c.1948G>A p.G650S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs779347611, COSV66480230; called by muse, mutect2
- ALPK1 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99455100; called by muse, mutect2, varscan2
- ALPK3 | c.3950G>A p.G1317D | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs148887150; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749566779, COSV51859710; called by muse, varscan2
- ANO10 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99428973; called by muse, mutect2, varscan2
- ANXA13 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs765446956, COSV51626397, COSV99146848; called by muse, varscan2
- AP1G2 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs749621105, COSV99846327; called by muse, mutect2, varscan2
- APLNR | c.1113_1114insA p.Y372Ifs*9 | Frame Shift Ins (INS) | VAF 24/67 reads (36%) | catalogued as COSV99951639; called by mutect2, pindel, varscan2
- ARAP1 | c.896G>A p.S299N (on ENST00000393609 / NM_001040118.2; = p.S54N on NM_015242.4) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV100502172; called by muse, mutect2, varscan2
- ARHGAP24 | c.443G>T p.G148V (on ENST00000395184 / NM_001025616.3; = p.G55V on NM_031305.3) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99982426; called by muse, varscan2
- ARHGEF15 | c.1366del p.R456Vfs*21 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs1567676744; called by mutect2, pindel, varscan2
- ARHGEF16 | c.1941G>T p.E647D | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101000574; called by muse, mutect2, varscan2
- ARID1B | c.3547dup p.Q1183Pfs*14 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | catalogued as rs1289067120; called by mutect2, varscan2
- ARID5B | c.1708C>A p.L570M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99690382; called by muse, mutect2, varscan2
- ARMCX3 | c.1117A>G p.M373V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.267); catalogued as COSV100362333; called by muse, mutect2, varscan2
- ASPM | c.9257T>C p.L3086P | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1171261676, COSV99661037; called by muse, mutect2
- ATP6V0A2 | c.1101del p.T368Lfs*43 | Frame Shift Del (DEL) | VAF 36/97 reads (37%) | catalogued as rs760459265; called by mutect2, varscan2
- ATP6V1H | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100778811; called by muse, mutect2, varscan2
- AVPR1B | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV100899451; called by muse, mutect2, varscan2
- AXL | c.1501C>T p.R501C (on ENST00000301178 / NM_021913.5; = p.R492C on NM_001699.6) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771047905, COSV56563398; called by muse, mutect2, varscan2
- B3GNT6 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1555027804; called by muse, mutect2
- BCL9L | c.3874G>A p.A1292T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs771126846, COSV52684875; called by muse, mutect2, varscan2
- BCOR | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs983329317, COSV100654051; called by muse, mutect2, varscan2
- BIRC3 | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99680205; called by muse, mutect2, varscan2
- BIRC6 | c.13487G>A p.R4496Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.092); catalogued as rs557307604, COSV70197596; called by muse, mutect2, varscan2
- BPTF | c.3259del p.I1087* | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | catalogued as rs757520968; called by mutect2, varscan2
- BRD1 | c.2657T>C p.L886P (on ENST00000216267 / NM_001349940.1; = p.L1017P on NM_001304808.3) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.467); catalogued as COSV99350240; called by muse, mutect2, varscan2
- BRD3 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57702161; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | catalogued as rs763134487; called by mutect2, varscan2
- BSN | c.1676_1677insT p.Q559Hfs*39 | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | catalogued as COSV99609690; called by mutect2, pindel, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD7 | c.2990C>T p.T997M | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.05); catalogued as rs374545941; called by muse, mutect2, varscan2
- C19orf57 | c.1151T>C p.L384S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100694843; called by muse, mutect2, varscan2
- C3orf56 | c.245T>A p.L82H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV67756162; called by muse, mutect2, varscan2
- C4orf17 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100431101; called by muse, mutect2, varscan2
- CACNA1S | c.1979C>A p.A660D | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100755351; called by muse, mutect2, varscan2
- CAMTA2 | c.3227C>A p.A1076D | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99236795; called by muse, mutect2, varscan2
- CAND1 | c.2294C>T p.T765I | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.649); catalogued as COSV101607353; called by muse, mutect2, varscan2
- CANT1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs751200931, COSV100185370; called by muse, mutect2, varscan2
- CATSPERB | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99831706; called by muse, mutect2, varscan2
- CATSPERE | c.2121dup p.F708Ifs*5 | Frame Shift Ins (INS) | VAF 24/73 reads (33%) | catalogued as rs1369590628; called by mutect2, pindel, varscan2
- CC2D1A | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs768143902, COSV99583067; ClinVar: uncertain significance; called by muse, varscan2
- CCDC17 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1296416528, COSV99322686; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 48/114 reads (42%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC90B | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99475309; called by muse, mutect2, varscan2
- CDH15 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as rs1487977733, COSV99228809; called by muse, mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs759091263; called by mutect2, varscan2
- CELSR2 | c.7414C>T p.R2472C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771008996, COSV54767020; called by mutect2, varscan2
- CEMP1 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99566117; called by muse, mutect2, varscan2
- CHST8 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99381612; called by muse, mutect2, varscan2
- CIT | c.3437G>T p.R1146L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV55877447, COSV99950822; called by muse, mutect2, varscan2
- CMKLR1 | c.379G>A p.V127I (on ENST00000312143 / NM_001142344.2; = p.V125I on NM_004072.3) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs374487323; called by muse, mutect2, varscan2
- CNGA1 | c.1327dup p.T443Nfs*3 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | catalogued as rs772867912; called by mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs374805044; called by mutect2, varscan2
- COG1 | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100245444; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 40/93 reads (43%) | catalogued as rs748995811; called by mutect2, varscan2
- COL16A1 | c.4494G>T p.Q1498H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV99595354; called by muse, mutect2, varscan2
- COL20A1 | c.2578C>T p.R860W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs369054383; called by muse, mutect2, varscan2
- COL5A1 | c.3905del p.P1302Rfs*186 | Frame Shift Del (DEL) | VAF 49/130 reads (38%) | catalogued as rs1564477140; called by mutect2, pindel, varscan2
- COL5A1 | c.4769G>A p.S1590N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.954); catalogued as COSV100880552; called by muse, mutect2
- COL6A3 | c.6618del p.G2207Efs*35 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | catalogued as COSV55080904; called by mutect2, pindel, varscan2
- CRACD | c.3515C>A p.A1172D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV51718865, COSV99949280; called by muse, mutect2
- CREBBP | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99271807; called by muse, mutect2, varscan2
- CRK | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100315755; called by muse, varscan2
- CSAD | c.1259G>A p.S420N (on ENST00000444623 / NM_001244705.2; = p.S447N on NM_015989.5) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV99915007; called by muse, mutect2, varscan2
- DAAM2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.508); catalogued as rs776862321, COSV51329286; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 29/55 reads (53%) | catalogued as rs751187768; called by mutect2, varscan2
- DCAF15 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.949); catalogued as rs376320375; called by muse, mutect2, varscan2
- DCTN1 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs752882353, COSV62620295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDN | c.1411del p.R471Efs*12 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as COSV100304819, COSV60291723; called by mutect2, pindel, varscan2
- DDX10 | c.1410+1G>A p.X470_splice | Splice Site (SNP) | VAF 24/58 reads (41%) | catalogued as rs779349091, COSV100489906; called by muse, mutect2, varscan2
- DDX56 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs955538329, COSV99346239; called by muse, mutect2, varscan2
- DENND1A | c.2687_2688del p.F896Wfs*39 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as rs1564390724; called by mutect2, pindel
- DENND4A | c.2066A>G p.E689G | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101475422; called by muse, mutect2, varscan2
- DFFB | c.608A>T p.N203I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100138791; called by muse, mutect2, varscan2
- DHX37 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV100439479; called by muse, mutect2, varscan2
- DIDO1 | c.3292G>A p.A1098T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as rs369951779; called by muse, mutect2, varscan2
- DLEC1 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs377618804; called by muse, mutect2, varscan2
- DMD | c.8887G>A p.V2963M | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756567967, COSV58889097, COSV58899060; called by muse, mutect2, varscan2
- DMPK | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs780659624, COSV99353643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.10258C>T p.Q3420* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV101209572; called by muse, mutect2, varscan2
- DNAJA1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs141132012; called by muse, mutect2, varscan2
- DNAJB12 | c.958C>T p.R320* (on ENST00000338820; = p.R286* on NM_017626.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100123933; called by muse, mutect2, varscan2
- DNAJC14 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100423712; called by muse, mutect2, varscan2
- DNMBP | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs772943085, COSV100144375; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK7 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs749097666, COSV52012342, COSV52019307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOP1B | c.4465C>T p.Q1489* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV101215799; called by muse, mutect2
- DRAP1 | c.560del p.P187Qfs*31 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as COSV100437183; called by mutect2, pindel, varscan2
- DTD2 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV100180127; called by muse, mutect2, varscan2
- DUOX2 | c.760C>A p.L254M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as COSV100545958; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs772082432; called by mutect2, varscan2
- DYSF | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV50300687, COSV50344552; called by muse, mutect2, varscan2
- EBF2 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs1467349351, COSV68776604; called by muse, mutect2, varscan2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | catalogued as COSV99653876; called by mutect2, pindel, varscan2
- EHD2 | c.1500G>A p.M500I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV99622211; called by muse, mutect2
- EIF2A | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs866479856, COSV99856130; called by muse, mutect2, varscan2
- EIF2AK3 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1434600602, COSV57550056, COSV57552838; called by muse, mutect2, varscan2
- EIF3I | c.904G>A p.G302S (on ENST00000373586; = p.G304S on NM_003757.3) | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV100753506; called by muse, mutect2, varscan2
- EPB41L1 | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs3210574, COSV99151586; called by muse, mutect2, varscan2
- ERBB3 | c.3910del p.H1304Mfs*7 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as COSV57256989; called by mutect2, pindel, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERMAP | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs771684891, COSV60275387; called by muse, mutect2, varscan2
- ERRFI1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs781338553, COSV66310438; called by muse, mutect2, varscan2
- ERV3-1 | c.1233G>A p.W411* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99276058; called by muse, mutect2, varscan2
- EYA1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.909); catalogued as rs142104253; called by muse, mutect2, varscan2
- FA2H | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99547929; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 37/82 reads (45%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM120B | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99379930; called by muse, mutect2, varscan2
- FCGBP | c.6529G>A p.V2177M | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1181929438, COSV99661473; called by muse, mutect2, varscan2
- FERMT3 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs778799174, COSV99656788; called by muse, mutect2
- FKBP8 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs556938614, COSV55893174; called by muse, mutect2, varscan2
- FKTN | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs139291792, COSV56310265; called by muse, mutect2, varscan2
- FLG | c.7141C>T p.Q2381* | Nonsense Mutation (SNP) | VAF 22/223 reads (10%) | catalogued as COSV100912099; called by muse, mutect2, varscan2
- FLNC | c.2007+2T>G p.X669_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100368686; called by muse, mutect2, varscan2
- FMO2 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99269330; called by muse, mutect2, varscan2
- FNDC3A | c.3460A>G p.T1154A (on ENST00000492622 / NM_001079673.2; = p.T1098A on NM_014923.5) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101256945; called by muse, mutect2, varscan2
- FNIP2 | c.3221G>A p.R1074Q | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs781687627, COSV100033272; called by muse, mutect2, varscan2
- FNTB | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99863095; called by muse, mutect2, varscan2
- FOXD4L5 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1381305137, COSV101073118, COSV101073169; called by muse, mutect2, varscan2
- FOXG1 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as COSV100487053; called by muse, mutect2, varscan2
- FPR2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319424621, COSV100389435; called by muse, mutect2, varscan2
- FREM1 | c.1559G>A p.S520N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1299491157, COSV101085366; called by muse, mutect2, varscan2
- FREM2 | c.8408C>T p.A2803V | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV54844518; called by muse, mutect2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs781034813; called by mutect2, pindel, varscan2
- GABRG1 | c.792del p.F264Lfs*3 | Frame Shift Del (DEL) | VAF 20/39 reads (51%) | catalogued as rs772301203; called by mutect2, varscan2
- GAL3ST1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.767); catalogued as rs1398726436, COSV100143239; called by muse, mutect2, varscan2
- GATA4 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1264782322, COSV100633019; called by muse, mutect2, varscan2
- GATD1 | c.473G>T p.R158M | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100168771; called by muse, mutect2
- GCKR | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs755324662, COSV53106701; called by muse, varscan2
- GCN1 | c.7177C>T p.R2393C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751152031, COSV56109374; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs763147690; called by mutect2, varscan2
- GK5 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV101242325; called by muse, mutect2, varscan2
- GLI3 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as CM990708, COSV101230027; called by muse, mutect2
- GLRX3 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs769979468, COSV100487987; called by muse, mutect2, varscan2
- GPR34 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100587734, COSV59363143; called by muse, mutect2, varscan2
- GPRIN2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs377375728; called by muse, mutect2, varscan2
- GRIA1 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs752447548, COSV53605030; ClinVar: not provided; called by muse, mutect2, varscan2
- GRIK2 | c.2546dup p.N849Kfs*11 | Frame Shift Ins (INS) | VAF 6/13 reads (46%) | catalogued as rs760757380; called by mutect2, varscan2
- GSX2 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100482619; called by muse, mutect2, varscan2
- GTF3A | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.738); catalogued as COSV100820212; called by muse, mutect2, varscan2
- GTPBP6 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100397830, COSV58204913; called by muse, mutect2, varscan2
- HADHB | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372980146; called by muse, mutect2, varscan2
- HCAR2 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV100186636; called by mutect2, varscan2
- HCAR3 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as rs1414898006, COSV63677231; called by muse, mutect2, varscan2
- HDHD5 | c.678del p.Y227Tfs*7 (on ENST00000336737 / NM_033070.3; = p.Y197Tfs*7 on NM_017829.5) | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as rs760251393; called by mutect2, pindel, varscan2
- HHIP | c.258del p.L87* | Frame Shift Del (DEL) | VAF 31/80 reads (39%) | catalogued as rs761690930, COSV56843525, COSV99667538; called by mutect2, pindel, varscan2
- HMCN1 | c.3422G>A p.R1141H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs370518238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.11006G>A p.R3669Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.993); catalogued as rs745313929, COSV54894177; ClinVar: uncertain significance; called by muse, mutect2
- HMGB2 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99632831; called by muse, mutect2, varscan2
- HMGCS2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101024912; called by muse, mutect2, varscan2
- HMGN5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100814788, COSV100815013; called by muse, mutect2, varscan2
- HP | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs368624883, COSV63326170; called by muse, mutect2, varscan2
- HPR | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99931023; called by muse, mutect2, varscan2
- HPS6 | c.1918G>A p.V640I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100154996; called by muse, mutect2, varscan2
- IFRD2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs587761145, COSV100269806; called by muse, mutect2, varscan2
- IGSF10 | c.5641G>A p.G1881S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99193867; called by muse, mutect2, varscan2
- IKBKE | c.1042del p.R348Dfs*32 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV65625022; called by mutect2, pindel, varscan2
- IL12RB2 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99255614; called by muse, mutect2, varscan2
- IMPDH2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs373752085; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | catalogued as rs1561359523; called by mutect2, varscan2
- IRF5 | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99977995; called by muse, mutect2, varscan2
- IRX1 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs771340310, COSV57359554; called by muse, mutect2, varscan2
- ITGAE | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1040691175, COSV99560766; called by muse, mutect2, varscan2
- ITPR3 | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100968075; called by muse, mutect2, varscan2
- JHY | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1227556628, COSV56221836; called by muse, mutect2, varscan2
- JPH2 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV100881796; called by muse, mutect2
- KANSL1 | c.2393-2A>G p.X798_splice | Splice Site (SNP) | VAF 50/117 reads (43%) | catalogued as COSV99294903; called by muse, mutect2, varscan2
- KCNA6 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768289; called by muse, mutect2, varscan2
- KCNJ12 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs781906064, COSV100056044; called by muse, mutect2, varscan2
- KCNN1 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.418); catalogued as COSV55837064; called by muse, mutect2
- KCNQ2 | c.863G>A p.W288* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV100610517; called by muse, mutect2, varscan2
- KCNT1 | c.2323A>G p.K775E (on ENST00000488444; = p.K794E on NM_020822.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV99706589; called by muse, mutect2, varscan2
- KCNV2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as rs1476130174, COSV101172642; called by muse, mutect2, varscan2
- KCTD1 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1272146130, COSV58683749; called by muse, mutect2, varscan2
- KHNYN | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as rs764395660, COSV52159682; called by muse, mutect2, varscan2
- KIAA0100 | c.1936A>G p.M646V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1297283643, COSV101197403; called by muse, mutect2, varscan2
- KIAA1217 | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100287206; called by muse, mutect2, varscan2
- KIF21A | c.2504G>A p.R835Q (on ENST00000361418 / NM_001378440.1; = p.R822Q on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as rs1351407142, COSV100735679, COSV62768050; called by muse, mutect2, varscan2
- KIF23 | c.1426_1427del p.S476Ffs*15 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs1220108679; called by pindel, varscan2
- KIF9 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.608); catalogued as rs201012739, COSV99646993; called by muse, mutect2, varscan2
- KIRREL1 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs749954360, COSV100780094; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHL10 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99509426; called by muse, mutect2, varscan2
- KMT2B | c.7550G>A p.R2517Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV99720568; called by muse, mutect2, varscan2
- KRTAP4-3 | c.367A>T p.S123C | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.819); catalogued as COSV101194172; called by muse, mutect2, varscan2
- L3MBTL2 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1405395333, COSV99346139; called by muse, mutect2, varscan2
- LAMB4 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99225466; called by muse, mutect2, varscan2
- LAMC1 | c.4712C>T p.A1571V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV99280362; called by muse, mutect2
- LETM2 | c.467A>G p.H156R (on ENST00000379957 / NM_001286819.2; = p.H109R on NM_144652.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as rs1223968080, COSV99907608; called by muse, mutect2, varscan2
- LIMS2 | c.482C>A p.P161H (on ENST00000355119 / NM_001161403.3; = p.P185H on NM_017980.4) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99760755; called by muse, mutect2, varscan2
- LIPE | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs143680557, COSV54926044; called by muse, mutect2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs762083435; called by mutect2, varscan2
- LPO | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV99229283; called by muse, mutect2, varscan2
- LRCH4 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1318708986, COSV59642745; called by muse, mutect2, varscan2
- LRP2 | c.9731T>C p.I3244T | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as rs1275010823, COSV99790077; called by muse, mutect2, varscan2
- LRRC8E | c.1361del p.P454Rfs*33 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs1388513289, COSV100143036; called by mutect2, pindel, varscan2
- LSM10 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs775621505, COSV100240117; called by muse, mutect2, varscan2
- MAB21L1 | c.698A>G p.Q233R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV100083807; called by muse, mutect2, varscan2
- MACF1 | c.20431-1G>A p.X6811_splice (on ENST00000372915; = p.X4856_splice on NM_012090.5) | Splice Site (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99246597; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 28/56 reads (50%) | catalogued as rs752439249; called by mutect2, varscan2
- MACROH2A2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1404408204, COSV64707223; called by muse, mutect2, varscan2
- MAFK | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1044531595, COSV99868780; called by muse, mutect2, varscan2
- MAL | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1256810902, COSV59431182; called by muse, mutect2, varscan2
- MAML1 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs375963318; called by muse, mutect2, varscan2
- MAN1C1 | c.958A>G p.S320G | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99848906; called by muse, mutect2, varscan2
- MAP3K14 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1445277946, COSV60925904; called by muse, mutect2, varscan2
- MAP7D2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV101107538; called by muse, mutect2
- MAP7D3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV60171013; called by muse, mutect2
- MAPK8 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV100827535; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 27/61 reads (44%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MAVS | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.05); catalogued as rs778085486, COSV100816399; ClinVar: not provided; called by muse, mutect2, varscan2
- MCM3AP | c.3690G>T p.K1230N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV52438499; called by muse, mutect2, varscan2
- MED13L | c.3833C>T p.A1278V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748882337, COSV56119547; called by muse, mutect2, varscan2
- MED24 | c.2414del p.P805Rfs*53 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as COSV56640006; called by mutect2, pindel, varscan2
- MEF2C | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100425979; called by muse, mutect2, varscan2
- MGAT4C | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV59829376; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs750307488; called by mutect2, varscan2
- MLLT10 | c.1231del p.V411* | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs747811015; called by mutect2, pindel, varscan2
- MMS22L | c.2818C>T p.Q940* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99247653; called by muse, mutect2, varscan2
- MOAP1 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV99365790; called by muse, mutect2, varscan2
- MOCS1 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs574721812, COSV99226898; ClinVar: uncertain significance; called by mutect2, varscan2
- MORN5 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101055983; called by muse, mutect2
- MPDZ | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100064482; called by muse, mutect2, varscan2
- MTG2 | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100895201; called by muse, mutect2, varscan2
- MTO1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100940546; called by muse, mutect2, varscan2
- MUC16 | c.31528A>G p.N10510D | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as COSV101201431; called by muse, mutect2, varscan2
- MUC16 | c.18340A>G p.T6114A | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV101201432; called by muse, mutect2, varscan2
- MUTYH | c.1321C>A p.H441N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100588168; called by muse, mutect2, varscan2
- MYBBP1A | c.1681A>G p.T561A | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99626865; called by muse, mutect2, varscan2
- MYBPH | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs140240759; called by muse, mutect2
- MYCN | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55257982, COSV99808532; called by muse, mutect2, varscan2
- MYH11 | c.5453C>T p.A1818V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs771343446, COSV100260153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO10 | c.5125G>T p.G1709C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99946189, COSV99946791; called by muse, mutect2, varscan2
- MYO10 | c.3184A>C p.S1062R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.035); catalogued as COSV99946192; called by muse, mutect2, varscan2
- MYO18B | c.3929C>T p.A1310V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs369078033, COSV100125036; called by muse, mutect2, varscan2
- MYO5C | c.4711C>T p.L1571F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs974578190, COSV99955408; called by muse, mutect2, varscan2
- N4BP1 | c.1146G>T p.E382D | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV99285550; called by muse, mutect2, varscan2
- NAB2 | c.1277-2A>C p.X426_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100272785; called by muse, mutect2, varscan2
- NACA2 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1358782386, COSV71713186; called by muse, mutect2, varscan2
- NASP | c.478del p.T160Qfs*29 | Frame Shift Del (DEL) | VAF 41/122 reads (34%) | catalogued as COSV100601638; called by mutect2, pindel, varscan2
- NAV1 | c.3632del p.K1211Rfs*17 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs770039235; called by mutect2, varscan2
- NCAPD3 | c.3652C>T p.P1218S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV101592173; called by muse, mutect2, varscan2
- NEURL2 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99509883, COSV99510126; called by muse, mutect2, varscan2
- NEUROD6 | c.856A>T p.N286Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99774184; called by muse, mutect2, varscan2
- NEXN | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99628975; called by muse, mutect2, varscan2
- NFATC4 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407599578, COSV99150940; called by muse, mutect2, varscan2
- NPAS2 | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs774452911, COSV100176902; called by muse, mutect2, varscan2
- NPHS1 | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs531280218, COSV62288352; called by muse, mutect2, varscan2
- NPS | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV101219428; called by muse, mutect2, varscan2
- NREP | c.205del p.*69Nfs*59 | Frame Shift Del (DEL) | VAF 65/183 reads (36%) | catalogued as COSV57405086; called by mutect2, pindel, varscan2
- NSD3 | c.2870A>C p.K957T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100395718; called by muse, mutect2, varscan2
- NUDT13 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760862650, COSV100624860; called by muse, mutect2, varscan2
- NUDT5 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as rs771778450, COSV66719191; called by muse, mutect2, varscan2
- OBSCN | c.6763T>C p.Y2255H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV99483853; called by muse, mutect2, varscan2
- OCA2 | c.2309A>G p.Y770C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100668600; called by muse, mutect2, varscan2
- OGFR | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs757955533, COSV51701872; called by muse, mutect2, varscan2
- OGT | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV101035604; called by muse, mutect2
- OR2H2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100590028; called by muse, mutect2, varscan2
- OR4E2 | c.455del p.G152Vfs*6 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | catalogued as rs764448584, COSV100330146; called by mutect2, pindel, varscan2
- OSCP1 | c.923T>C p.I308T (on ENST00000356637 / NM_001330493.1; = p.I298T on NM_145047.5) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99347537; called by muse, mutect2, varscan2
- P2RY4 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100997049; called by muse, mutect2, varscan2
- PACS2 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as rs782050259, COSV57657568; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.691G>A p.V231I (on ENST00000259318 / NM_001136562.3; = p.V462I on NM_007203.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs139564817, COSV52173723; called by muse, mutect2, varscan2
- PAN2 | c.1405A>C p.S469R | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99228489; called by muse, mutect2, varscan2
- PARP1 | c.1889A>C p.N630T | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV100829042; called by muse, mutect2, varscan2
- PARP14 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV101518688; called by muse, mutect2, varscan2
- PBX4 | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99232433; called by muse, mutect2, varscan2
- PCDHA8 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65327302; called by muse, mutect2
- PCDHB5 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50667832; called by muse, mutect2, varscan2
- PCDHGA2 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as COSV99546173; called by muse, mutect2, varscan2
- PCM1 | c.5912T>C p.L1971P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100279545; called by muse, mutect2, varscan2
- PDGFB | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776599710, CM159765, COSV100483596; called by muse, mutect2, varscan2
- PEDS1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs148820409; called by muse, mutect2, varscan2
- PEX13 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as rs146554084, CM111154; called by muse, mutect2, varscan2
- PFKL | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs776866454, COSV62465645; called by muse, mutect2, varscan2
- PHKA2 | c.3689C>T p.S1230L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs752371084, COSV66053720; called by muse, mutect2, varscan2
- PIK3R5 | c.1779A>C p.G593= | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99353807; called by muse, mutect2, varscan2
- PKM | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs751885485, COSV58790471; called by muse, mutect2, varscan2
- PKN3 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs754465307, COSV99403915; called by muse, mutect2
- PLD1 | c.823G>C p.V275L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV100578803; called by muse, mutect2, varscan2
- PLEC | c.2131C>T p.R711W (on ENST00000322810 / NM_201380.4; = p.R601W on NM_000445.5) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782724039, COSV59673209; called by muse, mutect2, varscan2
- PLPPR1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100883456; called by muse, mutect2, varscan2
- PLXNA1 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs150750071, COSV99304020; called by muse, mutect2, varscan2
- PNMA8A | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100562424; called by muse, mutect2, varscan2
- PODN | c.1264G>A p.V422M (on ENST00000395871; = p.V374M on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100439811; called by muse, mutect2, varscan2
- POLE | c.6072del p.V2025* | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs754630848; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- POT1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868664738, COSV100714137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRAF2 | c.397C>T p.L133= | Splice Region (SNP) | VAF 5/12 reads (42%) | catalogued as COSV59876738; called by muse, mutect2
- PRDM10 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1398258047, COSV100457014; called by muse, mutect2, varscan2
- PRKAR1B | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100816840; called by muse, mutect2, varscan2
- PRKCI | c.826dup p.T276Nfs*16 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | catalogued as rs753143066; called by mutect2, varscan2
- PRMT3 | c.1073-2A>C p.X358_splice | Splice Site (SNP) | VAF 43/108 reads (40%) | catalogued as COSV100424201; called by muse, mutect2, varscan2
- PRODH2 | c.485C>T p.A162V (on ENST00000301175; = p.A86V on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99995507; called by muse, mutect2, varscan2
- PRPF38B | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs771825453, COSV100898333; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 40/91 reads (44%) | catalogued as rs781858060; called by mutect2, varscan2
- PSIP1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs763000735, COSV101050999; called by muse, mutect2, varscan2
- PSMC6 | c.616G>A p.D206N (on ENST00000612399; = p.D192N on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.104); catalogued as COSV101471212; called by muse, mutect2, varscan2
- PSMD11 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs746642623, COSV99912627; called by muse, varscan2
- PTAR1 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as rs1399373232, COSV100466721; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs146650273; called by pindel, varscan2
- PTPRG | c.2165dup p.N722Kfs*45 | Frame Shift Ins (INS) | VAF 36/112 reads (32%) | catalogued as rs869306841; called by mutect2, varscan2
- PWWP3A | c.1702G>A p.A568T (on ENST00000627377; = p.A567T on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs886221936, COSV100262244; called by muse, mutect2, varscan2
- RAB6B | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs762430079, COSV99558274; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 33/93 reads (35%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RASAL3 | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100640334; called by muse, mutect2, varscan2
- RBFOX2 | c.457C>A p.L153I (on ENST00000438146 / NM_001349995.2; = p.L83I on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.344); catalogued as COSV99455768; called by muse, mutect2
- RBM33 | c.935A>C p.Q312P | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.544); catalogued as COSV100265700; called by muse, mutect2, varscan2
- RESF1 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100440583; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 20/32 reads (63%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RIMBP2 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV99900383; called by muse, mutect2, varscan2
- RIMS2 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.99); catalogued as COSV68113301; called by muse, mutect2, varscan2
- RIOK2 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV51615317; called by muse, mutect2, varscan2
- RNF121 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as rs756071313, COSV62317218; called by muse, mutect2, varscan2
- RNF128 | c.31dup p.W11Lfs*11 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF167 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs774643707, COSV99337561; called by muse, varscan2
- RNF24 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); catalogued as COSV100271164; called by muse, mutect2, varscan2
- RNF25 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99829202; called by muse, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 33/57 reads (58%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs752898741; called by mutect2, varscan2
- RPL10A | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100003570; called by muse, mutect2, varscan2
- RTN4 | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs761969807; called by mutect2, varscan2
- RXRA | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100709359; called by muse, mutect2, varscan2
- SCN1A | c.4229del p.N1410Mfs*2 (on ENST00000303395 / NM_001202435.3; = p.N1399Mfs*2 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | catalogued as CD126553, COSV100319575; called by mutect2, pindel, varscan2
- SCUBE3 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1374492329, COSV51460107, COSV99235200; called by muse, mutect2, varscan2
- SEC16A | c.6197del p.P2066Qfs*76 | Frame Shift Del (DEL) | VAF 37/95 reads (39%) | catalogued as COSV99256980; called by mutect2, pindel, varscan2
- SEC24D | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs142063505, COSV54881321; called by muse, mutect2, varscan2
- SEC63 | c.1689G>T p.K563N | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV100938404; called by muse, mutect2, varscan2
- SERPINE2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV99297001; called by muse, mutect2, varscan2
- SETD4 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139822807; called by muse, mutect2, varscan2
- SGF29 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100397050; called by muse, mutect2
- SH2D4B | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV100214236; called by muse, mutect2, varscan2
- SHCBP1L | c.720G>T p.E240D | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100772536; called by muse, mutect2, varscan2
- SI | c.66A>G p.I22M | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100017005; called by muse, mutect2, varscan2
- SIN3B | c.2791G>A p.V931I | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.707); catalogued as rs748832527, COSV56131573; called by muse, mutect2, varscan2
- SIRPD | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | PolyPhen benign (0.019); catalogued as COSV101065002; called by muse, mutect2, varscan2
- SLC17A1 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99766111; called by muse, mutect2, varscan2
- SLC22A18 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as COSV100388957; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC5A9 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99361971; called by muse, mutect2, varscan2
- SLC6A12 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV100675215; called by muse, mutect2, varscan2
- SLC6A2 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs758951794, COSV54920133; called by muse, mutect2, varscan2
- SLC8A3 | c.1453A>G p.S485G | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV100776365; called by muse, mutect2, varscan2
- SLCO1C1 | c.1178T>C p.F393S | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV99859924; called by muse, mutect2, varscan2
- SLFN13 | c.2586G>T p.R862S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99540340; called by muse, mutect2, varscan2
- SMAD1 | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV100129916; called by muse, mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs749889899; called by mutect2, varscan2
- SMTNL2 | c.543del p.R182Gfs*5 (on ENST00000389313 / NM_001114974.2; = p.R38Gfs*5 on NM_198501.3) | Frame Shift Del (DEL) | VAF 10/126 reads (8%) | catalogued as COSV58807509; called by mutect2, pindel
- SNX10 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100640138; called by muse, mutect2, varscan2
- SOX9 | c.184_186del p.K62del | In Frame Del (DEL) | VAF 36/102 reads (35%) | catalogued as rs778226772; called by pindel, varscan2
- SP5 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV100935359; called by muse, varscan2
- SPINK13 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.173); catalogued as COSV101268321; called by muse, mutect2, varscan2
- SPRY1 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as COSV100201929; called by muse, mutect2, varscan2
- SPTB | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs1399245468, COSV101072396; called by muse, mutect2, varscan2
- SPTBN4 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV58948932; called by muse, mutect2, varscan2
- SRRT | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs778872288, COSV100730350; called by muse, mutect2, varscan2
- SSH2 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV99282943; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 32/79 reads (41%) | PolyPhen probably damaging (0.999); catalogued as rs116716486, COSV100083780; called by muse, mutect2, varscan2
- STAT6 | c.2444dup p.G816Rfs*139 | Frame Shift Ins (INS) | VAF 19/50 reads (38%) | catalogued as rs749654830; called by mutect2, pindel, varscan2
- STIP1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs946652004, COSV100534769, COSV100534966; called by muse, mutect2, varscan2
- STON1 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs761962005, COSV100562260; called by muse, mutect2, varscan2
- SVEP1 | c.3928G>T p.E1310* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100238956; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SVIP | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375026736; called by muse, mutect2, varscan2
- SYNDIG1 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.232); catalogued as rs747872130, COSV65239071; called by muse, mutect2, varscan2
- SYT14 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99656043; called by muse, mutect2, varscan2
- TANC2 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs976637040, COSV67332248; called by muse, mutect2, varscan2
- TBCD | c.3218C>T p.A1073V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as rs780333606, COSV62801197; called by muse, mutect2, varscan2
- TBX4 | c.1129A>T p.M377L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99540650; called by muse, mutect2, varscan2
- TBXA2R | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1271416561, COSV64343449; called by muse, mutect2
- TC2N | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.841); catalogued as rs767310568, COSV100562999; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs756457255; called by mutect2, pindel, varscan2
- TKTL2 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548015097, COSV99761712; called by muse, mutect2, varscan2
- TMEFF2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.143); catalogued as COSV99772344; called by muse, mutect2, varscan2
- TMEM200A | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs200272604, COSV99760018; called by muse, varscan2
- TMEM204 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1567348734, COSV99560168; called by muse, mutect2, varscan2
- TMEM256 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.257); catalogued as COSV100192897, COSV56658709; called by muse, mutect2, varscan2
- TNK2 | c.1482del p.D495Tfs*3 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs750898925, COSV100361004; called by mutect2, pindel, varscan2
- TOX3 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99568100; called by muse, mutect2, varscan2
- TREX2 | c.415G>A p.A139T (on ENST00000334497; = p.A96T on NM_080701.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as rs782797044, COSV57847778; called by muse, mutect2, varscan2
- TRIM11 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52858140, COSV99488935; called by muse, mutect2, varscan2
- TRIM16L | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs757995912, COSV67459023; called by muse, mutect2, varscan2
- TRIM5 | c.1123del p.V375Yfs*28 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | catalogued as rs1394654131; called by mutect2, pindel, varscan2
- TRPC6 | c.2485-2A>G p.X829_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100723753; called by muse, mutect2, varscan2
- TRPC6 | c.1411C>A p.L471I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV100723513, COSV100723754; called by muse, mutect2, varscan2
- TSC1 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV100052536; called by muse, mutect2, varscan2
- TSHZ3 | c.2155G>A p.V719I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.138); catalogued as rs1398877027, COSV99552608; called by muse, mutect2, varscan2
- TSPAN7 | c.516del p.S173Afs*4 | Frame Shift Del (DEL) | VAF 30/68 reads (44%) | catalogued as rs752121179, COSV54531581; called by mutect2, varscan2
- TTC12 | c.323-1G>A p.X108_splice | Splice Site (SNP) | VAF 15/38 reads (39%) | catalogued as rs1555140661, COSV100133334; called by muse, mutect2, varscan2
- TTC13 | c.1643A>T p.N548I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV100793012; called by muse, mutect2, varscan2
- TTN | c.88207G>A p.G29403S (on ENST00000591111; = p.G21979S on NM_003319.4) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | PolyPhen possibly damaging (0.721); catalogued as rs750213547, COSV60054876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.28777A>T p.T9593S (on ENST00000591111; = p.T8666S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | PolyPhen benign (0.061); catalogued as COSV100628155; called by muse, mutect2, varscan2
- TTN | c.6043G>A p.A2015T (on ENST00000591111; = p.A1969T on NM_003319.4) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | PolyPhen possibly damaging (0.777); catalogued as rs776534823, COSV59991879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB6 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99302151; called by muse, mutect2, varscan2
- TUT1 | c.1875G>T p.Q625H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.188); catalogued as COSV99545570; called by muse, mutect2, varscan2
- UBASH3B | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1347571442, COSV99418751; called by muse, mutect2, varscan2
- USP9X | c.2831C>T p.A944V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV61068102; called by muse, mutect2, varscan2
- USP9X | c.7288C>T p.P2430S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.391); catalogued as COSV100200046; called by muse, mutect2, varscan2
- VARS1 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100989963; called by muse, mutect2, varscan2
- VWF | c.4021C>T p.R1341W | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61749402, CM982033, COSV54628453; ClinVar: not provided; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDR88 | c.703T>A p.S235T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV100866627, COSV63451376; called by muse, mutect2, varscan2
- WNT10B | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99976079; called by muse, mutect2, varscan2
- WWC2 | c.616dup p.M206Nfs*9 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | catalogued as rs760401865; called by mutect2, varscan2
- YY1AP1 | c.590G>A p.S197N (on ENST00000295566 / NM_139118.2; = p.S120N on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as COSV99804627; called by muse, mutect2, varscan2
- ZBED4 | c.2398G>A p.G800S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs778125458, COSV53465603, COSV53466821; called by muse, mutect2, varscan2
- ZBTB1 | c.1147del p.S383Vfs*6 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs747075448, COSV62437585; called by mutect2, varscan2
- ZBTB18 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV62397098; called by muse, mutect2, varscan2
- ZBTB7C | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs759037179, COSV100134449; called by muse, mutect2, varscan2
- ZFHX3 | c.8978G>A p.W2993* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99214520; called by muse, mutect2
- ZFHX3 | c.2551G>A p.G851S | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.069); catalogued as rs1356895082, COSV99214526; called by muse, mutect2, varscan2
- ZFHX4 | c.6554G>A p.R2185Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99267070; called by muse, mutect2, varscan2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 56/137 reads (41%) | catalogued as rs751974853; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 40/114 reads (35%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF182 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100527196; called by muse, mutect2
- ZNF214 | c.1031T>C p.L344S | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99547635; called by muse, mutect2, varscan2
- ZNF32 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as COSV100986516; called by muse, mutect2, varscan2
- ZNF548 | c.1217G>A p.C406Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV100278286; called by muse, mutect2, varscan2
- ZNF608 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100102373; called by muse, mutect2, varscan2
- ZNF625 | c.480del p.K161Nfs*23 | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | catalogued as COSV63242073; called by mutect2, pindel, varscan2
- ZNF687 | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs764664257, COSV55020343; called by muse, mutect2, varscan2
- ZNF689 | c.524del p.K175Sfs*102 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as COSV54908979; called by mutect2, pindel, varscan2
- ZNF750 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766759859, COSV53961852; called by muse, mutect2, varscan2
- ZNF862 | c.2453G>T p.G818V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1263684822, COSV99783776; called by muse, mutect2, varscan2
- AATF | c.446T>C p.F149S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- ABCF1 | c.118del p.T40Rfs*8 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- AGBL1 | c.909dup p.E304* | Frame Shift Ins (INS) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- ALK | c.2080del p.H694Mfs*17 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | called by mutect2, pindel, varscan2
- ANAPC2 | c.2239_2241del p.K747del | In Frame Del (DEL) | VAF 13/26 reads (50%) | called by mutect2, pindel, varscan2
- AP5M1 | c.443del p.N148Mfs*5 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- APOA4 | c.498_499del p.R166Sfs*40 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by pindel, varscan2
- ARID5B | c.1289del p.Q430Rfs*49 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, varscan2
- ARMC4 | c.1730del p.G577Vfs*9 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- BCS1L | c.467_468del p.E156Afs*19 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by pindel, varscan2
- CCDC102B | c.108del p.R37Gfs*89 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- CDC42 | c.247del p.S83Qfs*11 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- CDK4 | c.618_619del p.E206Dfs*13 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | called by pindel, varscan2
- CHRND | c.922del p.I309Sfs*17 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- COL27A1 | c.3365del p.P1122Qfs*45 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- CORO2A | c.1427del p.P476Hfs*26 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- CPEB4 | c.2048del p.F683Sfs*32 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- CRIM1 | c.2567del p.P856Lfs*67 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- CTCF | c.456del p.M153* | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- CUL1 | c.710del p.L237Wfs*25 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- DENND4B | c.3263del p.P1088Qfs*42 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel
- DEPDC7 | c.903_905del p.L302del (on ENST00000241051 / NM_001077242.2; = p.L293del on NM_139160.2) | In Frame Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- DLG1 | c.1625_1627del p.V542del | In Frame Del (DEL) | VAF 20/44 reads (45%) | called by pindel, varscan2
- DNAJC7 | c.1106del p.N369Mfs*6 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- DUSP6 | c.918_919dup p.Y307Ffs*11 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- DVL3 | c.1631del p.P544Rfs*124 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- EVPL | c.5829del p.L1944Sfs*20 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- FAM111A | c.1439del p.K480Sfs*8 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- FBP1 | c.544del p.V182Sfs*20 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- FBXO48 | c.439del p.E147Kfs*3 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- FHDC1 | c.304del p.W102Gfs*55 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel
- FNDC1 | c.4197del p.V1400Wfs*2 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | called by mutect2, pindel, varscan2
- FOXA2 | c.1041_1048del p.H348Gfs*11 (on ENST00000377115 / NM_153675.3; = p.H354Gfs*11 on NM_021784.5) | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel
- FOXP4 | c.798del p.K267Rfs*100 (on ENST00000307972 / NM_001012426.1; = p.K266Rfs*100 on NM_138457.3) | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- GAGE12J | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- GDPD5 | c.1775del p.G592Vfs*9 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- HACE1 | c.2396del p.N799Ifs*22 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- HDAC4 | c.2703del p.M902Wfs*55 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- IL17RA | c.2338_2339del p.T780Afs*13 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by pindel, varscan2
- IL31RA | c.1731del p.K577Nfs*5 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- IRF2 | c.500del p.N167Mfs*7 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- ITPR1 | c.5700dup p.A1901Sfs*2 (on ENST00000354582; = p.A1846Sfs*2 on NM_002222.7) | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- KDM6B | c.1960del p.Q654Sfs*46 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- KIAA1755 | c.3236dup p.V1080Cfs*58 | Frame Shift Ins (INS) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- KIF11 | c.2018del p.K673Rfs*3 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- KIF26B | c.6017del p.G2006Vfs*13 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- KIF3C | c.996del p.N333Mfs*7 | Frame Shift Del (DEL) | VAF 39/112 reads (35%) | called by mutect2, pindel, varscan2
- KLK1 | c.42del p.T15Lfs*89 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- MAP1B | c.5901del p.E1968Kfs*2 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- MRTFA | c.2215del p.Q739Sfs*33 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, varscan2
- MTAP | c.571del p.A191Rfs*6 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- MTSS2 | c.1677del p.G560Afs*34 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- NEDD4L | c.467del p.N156Mfs*51 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- NSD1 | c.7349del p.N2450Ifs*6 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- NT5C | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OCIAD2 | c.339del p.F113Lfs*27 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- OSBPL6 | c.327del p.F109Lfs*8 | Frame Shift Del (DEL) | VAF 36/121 reads (30%) | called by mutect2, pindel, varscan2
- P2RX4 | c.605+3_605+6del p.X202_splice | Splice Site (DEL) | VAF 18/64 reads (28%) | called by pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- PCDHGC5 | c.1024del p.D342Mfs*19 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
- PHACTR4 | c.1037del p.P346Hfs*33 (on ENST00000373839 / NM_001350159.2; = p.P356Hfs*33 on NM_023923.4) | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- PHF1 | c.16del p.R6Gfs*2 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- PHLDB1 | c.1377del p.L460* | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- PIK3C2B | c.859del p.R287Afs*92 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.244del p.I82Sfs*32 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- PKD1 | c.6262del p.R2088Gfs*28 | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | called by mutect2, pindel, varscan2
- PKD1 | c.1426del p.V476Wfs*82 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- PMM1 | c.256_257del p.K86Afs*104 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- PPP3CB | c.101del p.P34Qfs*5 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel
- PRKDC | c.8110del p.R2704Gfs*13 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- PTEN | c.504del p.S170Vfs*13 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- PTPN5 | c.1458del p.H488Tfs*38 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- QSOX2 | c.1790dup p.E598Rfs*58 | Frame Shift Ins (INS) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | called by pindel, varscan2
- RPL22 | c.267del p.K89Nfs*3 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | called by mutect2, pindel, varscan2
- RPL22L1 | c.211_212del p.Q71Vfs*3 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | called by mutect2, varscan2
- RUSC2 | c.886del p.R296Vfs*132 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- SEZ6L2 | c.2529del p.N844Tfs*10 (on ENST00000308713 / NM_001114099.3; = p.N787Tfs*10 on NM_012410.4) | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- SLC12A7 | c.236dup p.N79Kfs*275 | Frame Shift Ins (INS) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- SLC16A11 | c.827dup p.Y277Ifs*125 (on ENST00000308009; = p.Y253Ifs*125 on NM_153357.3) | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- SLC37A2 | c.324del p.F108Lfs*58 | Frame Shift Del (DEL) | VAF 13/131 reads (10%) | called by mutect2, pindel, varscan2
- SLC39A7 | c.931del p.R311Efs*3 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- SLC8A1 | c.2381del p.P794Lfs*17 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- SP100 | c.14del p.G5Afs*4 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | called by mutect2, pindel, varscan2
- SPAG9 | c.244_246del p.N82del | In Frame Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel
- SPEN | c.7826del p.K2609Rfs*29 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- SPRY4 | c.520del p.R174Gfs*85 (on ENST00000434127 / NM_001127496.3; = p.R197Gfs*85 on NM_030964.4) | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- SSX2 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- SUPT16H | c.3126del p.K1043Rfs*8 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- TARS3 | c.444_447del p.L149Pfs*15 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- THAP9 | c.454del p.R152Dfs*5 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- TNF | c.69del p.Q25Rfs*15 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- TNRC6B | c.1636del p.L546Sfs*63 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- TNRC6B | c.4523del p.G1508Vfs*8 (on ENST00000454349 / NM_001162501.2; = p.G1398Vfs*8 on NM_015088.3) | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.594del p.V199* (on ENST00000343537 / NM_001031685.3; = p.V70* on NM_005426.2) | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | called by mutect2, pindel, varscan2
- TUBGCP4 | c.492dup p.L165Vfs*21 | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- VARS1 | c.1858del p.A620Pfs*25 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- VPS13B | c.173del p.L58* | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- XPC | c.1525del p.R509Efs*17 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- YLPM1 | c.761del p.P254Lfs*35 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- ZHX3 | c.1333del p.L445Sfs*3 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- ZNF184 | c.387dup p.H130Tfs*5 | Frame Shift Ins (INS) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- ZNF70 | c.195dup p.N66Efs*23 | Frame Shift Ins (INS) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- ZNF776 | c.366del p.K122Nfs*31 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, varscan2
- ZNF84 | c.1930A>G p.N644D | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AC006059.2 | c.1551C>T p.G517= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV100045907, COSV59607216; called by muse, mutect2, varscan2
- AGO2 | c.1941C>T p.R647= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs749601049, COSV99596333; called by muse, mutect2, varscan2
- AICDA | c.198G>A p.S66= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV57565821; called by muse, varscan2
- ANGPT4 | c.342G>A p.S114= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs943789944, COSV101124867; called by muse, mutect2, varscan2
- ANKDD1A | c.876C>A p.A292= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100731281; called by muse, mutect2, varscan2
- APBA2 | c.2121C>T p.S707= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs148579265, COSV101382103; called by muse, mutect2, varscan2
- ATAD3C | c.1125C>T p.T375= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as rs1201647964, COSV100426602; called by muse, mutect2, varscan2
- ATRX | c.1539A>G p.L513= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as COSV100971360; called by muse, mutect2, varscan2
- BAHD1 | c.2193C>T p.P731= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs1444745334, COSV100087081; called by muse, mutect2, varscan2
- BANP | c.1260C>T p.H420= (on ENST00000286122; = p.H392= on NM_017869.4) | Silent (SNP) | VAF 56/146 reads (38%) | catalogued as rs755258976, COSV53741136; called by muse, mutect2, varscan2
- BCAR3 | c.1110C>T p.S370= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs200521070, COSV99551201; called by muse, mutect2, varscan2
- BCAS3 | c.1890A>G p.R630= (on ENST00000390652 / NM_001353144.2; = p.R615= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV101176974; called by muse, mutect2, varscan2
- CDH16 | c.2121T>C p.G707= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100234156; called by muse, mutect2, varscan2
- CMPK2 | c.1056G>A p.L352= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV56774028, COSV99879014; called by muse, mutect2, varscan2
- COL12A1 | c.7404T>C p.L2468= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100486416; called by muse, mutect2, varscan2
- COL17A1 | c.4062C>T p.G1354= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100212096; called by muse, mutect2, varscan2
- CSNK1A1 | c.975G>A p.K325= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99939767; called by muse, mutect2
- CTTNBP2 | c.1227C>T p.T409= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs367880685; called by muse, mutect2, varscan2
- DDX42 | c.1749G>A p.T583= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs774488957, COSV63790708; called by muse, mutect2, varscan2
- DEFB128 | c.235C>T p.L79= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV100544466; called by muse, mutect2, varscan2
- DHX38 | c.2580G>A p.T860= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs527396907, COSV99194562; called by muse, mutect2, varscan2
- DIPK1B | c.1110C>T p.C370= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs755812718, COSV100765504; called by muse, mutect2, varscan2
- DIS3L | c.660C>T p.S220= (on ENST00000319212 / NM_001143688.3; = p.S137= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100055560; called by muse, mutect2, varscan2
- DKK1 | c.12G>A p.L4= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100906578; called by muse, mutect2
- DNAH17 | c.8493C>T p.Y2831= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs964979239, COSV67760515; called by muse, mutect2, varscan2
- DNAH3 | c.4608T>C p.A1536= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV99770338; called by muse, mutect2, varscan2
- DSG3 | c.1758C>T p.V586= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV99934693; called by muse, mutect2, varscan2
- ELOA2 | c.501C>A p.R167= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV99797930; called by muse, mutect2, varscan2
- ENPP6 | c.1011G>A p.P337= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1157222892, COSV99699120; called by muse, mutect2, varscan2
- ERMP1 | c.1977T>C p.C659= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV99284749; called by muse, mutect2
- ESR2 | c.589C>A p.R197= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs760053106, CM142389, COSV50831269, COSV99963815; called by muse, mutect2, varscan2
- EXD3 | c.477C>T p.G159= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs762148096, COSV100573916; called by muse, mutect2, varscan2
- FAN1 | c.1659G>A p.S553= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs202227554, COSV100756080; called by muse, mutect2, varscan2
- FASN | c.2832C>T p.F944= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs755643560, COSV60751980; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXL2 | c.438C>G p.R146= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs781285704, COSV57730582; called by muse, mutect2, varscan2
- GALC | c.1449C>A p.S483= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV99730444; called by muse, mutect2, varscan2
- GAS2L3 | c.513C>T p.Y171= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as rs550935707, COSV57157528, COSV99903129; called by muse, mutect2
- GLI2 | c.360G>A p.P120= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs781740772, COSV58039410; called by muse, mutect2, varscan2
- GLYCTK | c.1134A>G p.A378= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs1435330836, COSV99980930; called by muse, mutect2, varscan2
- GPN3 | c.54C>A p.T18= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99959962; called by muse, mutect2, varscan2
- GPR132 | c.354C>T p.T118= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs755588893, COSV100317721; called by muse, mutect2, varscan2
- GPR39 | c.1011G>A p.S337= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1558870597, COSV61415842; called by muse, mutect2, varscan2
- GRIN2C | c.1587G>A p.T529= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs376756291; called by muse, mutect2, varscan2
- GTF3C6 | c.447C>T p.D149= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs759091734, COSV100328790; called by muse, mutect2, varscan2
- HAND2 | c.588C>T p.N196= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100854237; called by muse, mutect2, varscan2
- HAUS2 | c.369T>G p.P123= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99535526; called by muse, mutect2, varscan2
- HDAC5 | c.1209C>A p.A403= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV99871015; called by muse, mutect2, varscan2
- HECTD4 | c.8292C>T p.D2764= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV101108352; called by muse, mutect2, varscan2
- HMCN1 | c.13539C>T p.N4513= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99635071; called by muse, mutect2, varscan2
- ICE1 | c.2115C>A p.A705= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99665611; called by muse, mutect2, varscan2
- IGHD3-10 | c.30A>G p.*10= | Silent (SNP) | VAF 116/256 reads (45%) | called by muse, mutect2, varscan2
- IGSF10 | c.2991T>C p.P997= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV99193871; called by muse, mutect2, varscan2
- IKZF1 | c.102C>T p.P34= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs776947333, COSV100498719; called by muse, mutect2, varscan2
- IRF9 | c.255C>T p.R85= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1452850740, COSV100138272; called by muse, mutect2, varscan2
- IRGC | c.291G>A p.S97= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs11555892; called by mutect2, varscan2
- KATNAL1 | c.1293A>G p.A431= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV101017156; called by muse, mutect2, varscan2
- KCNK15 | c.564C>T p.H188= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100865212; called by muse, mutect2
- LAMA1 | c.8964T>C p.R2988= | Silent (SNP) | VAF 59/154 reads (38%) | catalogued as COSV101057618, COSV67534472; called by muse, mutect2, varscan2
- LAMB4 | c.2868C>T p.F956= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs767544532, COSV52714379, COSV99225464; called by muse, mutect2, varscan2
- MAP9 | c.1176G>A p.S392= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs762649412, COSV60904781, COSV60906622; called by muse, mutect2, varscan2
- MATN2 | c.1527G>A p.Q509= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99647087; called by muse, mutect2, varscan2
- MBP | c.192G>A p.V64= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100592897; called by muse, mutect2, varscan2
- MCMBP | c.867C>T p.D289= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100750168; called by muse, mutect2, varscan2
- MIB1 | c.2466C>T p.C822= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99839411; called by muse, mutect2, varscan2
- MIER2 | c.18G>A p.S6= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs554947249, COSV99316260; called by muse, varscan2
- MN1 | c.1392C>T p.S464= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV100180118; called by muse, mutect2, varscan2
- MROH7 | c.1335C>T p.S445= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100273985; called by muse, mutect2, varscan2
- MTA1 | c.1113C>T p.N371= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100495393; called by muse, mutect2, varscan2
- MTMR6 | c.117C>T p.I39= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs371374084, COSV101110787, COSV101110843; called by muse, mutect2, varscan2
- MUC17 | c.7195C>T p.L2399= | Silent (SNP) | VAF 59/134 reads (44%) | catalogued as rs1348237250, COSV60301840; called by muse, mutect2, varscan2
- MUC21 | c.768C>A p.T256= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as COSV100888916; called by muse, mutect2, varscan2
- MYH13 | c.4839C>T p.N1613= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs753157072, COSV99355353; called by muse, mutect2, varscan2
- MYH6 | c.2325G>T p.L775= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100676967; called by muse, mutect2, varscan2
- NAB2 | c.1041C>T p.S347= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV55666591; called by muse, mutect2, varscan2
- NARS1 | c.504C>T p.Y168= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99900726; called by muse, mutect2, varscan2
- NCOA6 | c.792G>A p.Q264= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs772784924, COSV62860937; called by muse, mutect2, varscan2
- NCOR1 | c.4653C>T p.H1551= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99251874; called by muse, mutect2, varscan2
- NDST2 | c.1119C>T p.D373= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs755046559, COSV100014344; called by muse, mutect2, varscan2
- NOMO3 | c.1647C>T p.N549= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1343081464, COSV99530947; called by mutect2, varscan2
- NTRK2 | c.1233G>A p.T411= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as rs141562338; called by muse, mutect2, varscan2
- OBSCN | c.7431C>T p.P2477= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV99483856; called by muse, mutect2, varscan2
- PFAS | c.337C>T p.L113= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100119124; called by muse, mutect2, varscan2
- PFKL | c.156C>T p.Y52= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs531863342, COSV62462770; called by muse, mutect2, varscan2
- PID1 | c.597C>T p.A199= (on ENST00000354069 / NM_001330156.1; = p.A197= on NM_017933.5) | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs542027380, COSV62475637; called by muse, mutect2, varscan2
- PIGV | c.1146C>T p.Y382= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs761952861, COSV99315132; called by muse, varscan2
- PIP5K1C | c.961C>T p.L321= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs141889838; called by muse, mutect2, varscan2
- PLA2G4F | c.1500C>T p.N500= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as rs377757066; called by muse, mutect2, varscan2
- POLR1A | c.4320C>T p.N1440= | Silent (SNP) | VAF 73/165 reads (44%) | catalogued as rs201493508, COSV99808356; called by muse, mutect2, varscan2
- PPP2R2D | c.1008C>T p.R336= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV101409071; called by muse, mutect2, varscan2
- PRDM16 | c.933C>T p.C311= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV54591364; called by muse, mutect2, varscan2
- PRSS22 | c.609C>T p.I203= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as rs1049497419, COSV50721019; called by muse, mutect2, varscan2
- PTPN12 | c.1086G>A p.V362= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs779355171, COSV99950689; called by muse, mutect2, varscan2
- PTPRJ | c.1173C>T p.N391= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs147639990; called by muse, mutect2, varscan2
- PTPRN2 | c.1380G>A p.Q460= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV101235292; called by muse, mutect2, varscan2
- RAB37 | c.282C>T p.S94= (on ENST00000392613 / NM_001006638.3; = p.S87= on NM_175738.5) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs763968925, COSV100463611; called by muse, mutect2, varscan2
- RAB3GAP2 | c.624G>A p.L208= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99424975; called by muse, mutect2, varscan2
- RBM12B | c.2625G>A p.P875= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs369223333; called by muse, mutect2, varscan2
- RELN | c.696C>T p.G232= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV59016682; called by muse, mutect2, varscan2
- RFLNA | c.390C>T p.T130= (on ENST00000546355 / NM_001365156.1; = p.T49= on NM_181709.4) | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs372026151; called by muse, mutect2, varscan2
- RNF123 | c.642C>T p.N214= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs371440681; called by muse, mutect2, varscan2
- RNF123 | c.2199G>C p.R733= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV100571174; called by muse, mutect2, varscan2
- RUSF1 | c.864C>T p.N288= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs370067641, COSV100393396; called by muse, mutect2, varscan2
- SEPTIN4 | c.246G>A p.S82= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs774598820; called by muse, mutect2
- SIRT6 | c.93G>A p.E31= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100511428; called by muse, mutect2, varscan2
- SLC12A9 | c.2178G>T p.V726= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99308158; called by muse, mutect2, varscan2
- SLC16A5 | c.1287C>T p.V429= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs535752297, COSV61675454; called by muse, mutect2, varscan2
- SLC39A8 | c.576C>T p.V192= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs370212187; called by muse, mutect2, varscan2
- SLC7A10 | c.684G>A p.T228= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs370154278; called by muse, mutect2, varscan2
- SMARCC2 | c.3222G>A p.A1074= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV53237940, COSV99519453; called by muse, mutect2, varscan2
- SMARCE1 | c.84C>T p.Y28= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100796048; called by muse, mutect2, varscan2
- SMC1B | c.2496G>A p.L832= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100663488; called by muse, mutect2, varscan2
- SMURF1 | c.2103G>A p.A701= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs569191641, COSV62815857; called by muse, mutect2, varscan2
- SOX30 | c.564G>A p.A188= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV99398747; called by muse, mutect2, varscan2
- SPACA1 | c.666G>A p.V222= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV99389755; called by muse, mutect2, varscan2
- SPDYE5 | c.558G>A p.R186= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- SPTBN5 | c.1606C>T p.L536= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV58021075; called by muse, mutect2, varscan2
- SSTR1 | c.66C>T p.G22= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV99943126; called by muse, mutect2, varscan2
- SYNE2 | c.267G>A p.Q89= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV58362556; called by muse, mutect2, varscan2
- TAAR6 | c.84G>A p.S28= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as COSV99256890; called by muse, mutect2, varscan2
- TCF12 | c.1083A>G p.S361= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99978847; called by muse, mutect2
- TECTA | c.2565C>T p.N855= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs747008995, COSV99881419; called by muse, mutect2, varscan2
- TGS1 | c.2322A>G p.A774= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs1348476315, COSV99485722; called by muse, mutect2, varscan2
- TNFRSF19 | c.435C>T p.Y145= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs772491427, COSV99947714; called by muse, mutect2, varscan2
- TNS2 | c.2292G>A p.G764= (on ENST00000314250 / NM_170754.4; = p.G774= on NM_015319.2) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV100036893; called by muse, mutect2, varscan2
- TNS4 | c.1005C>T p.P335= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99564127; called by muse, mutect2, varscan2
- TRIM65 | c.1167C>T p.R389= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs192870761, COSV53932863; called by muse, mutect2, varscan2
- TRIM9 | c.768C>T p.G256= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100032154; called by muse, mutect2, varscan2
- TTC38 | c.606C>T p.L202= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs111289634; called by muse, mutect2, varscan2
- TTYH1 | c.1296C>T p.D432= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs760407661, COSV100002405; called by muse, mutect2, varscan2
- TXNRD2 | c.1176C>T p.Y392= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs544242322, COSV101266075; ClinVar: likely benign; called by muse, mutect2, varscan2
- VARS2 | c.3183G>T p.P1061= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV100423066; called by muse, varscan2
- WDR27 | c.1587G>A p.V529= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100359736; called by muse, mutect2, varscan2
- WDR3 | c.1926A>G p.V642= | Silent (SNP) | VAF 4/81 reads (5%) | catalogued as rs964142298, COSV100310407; called by muse, mutect2
- WNK2 | c.1776G>A p.P592= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1361931274, COSV99944353; called by muse, mutect2, varscan2
- ZFHX3 | c.7299G>A p.A2433= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as rs767810299, COSV51708267; called by muse, mutect2, varscan2
- ZFHX3 | c.4074A>G p.S1358= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV51716019, COSV99214525; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1719C>T p.C573= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs144470614; called by muse, mutect2, varscan2
- ZNF12 | c.1290C>A p.T430= (on ENST00000405858 / NM_016265.4; = p.T392= on NM_006956.3) | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100703864; called by muse, mutect2, varscan2
- ZNF484 | c.36C>T p.D12= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs750044061, COSV60256751; called by muse, mutect2, varscan2
- ZNF500 | c.651G>A p.S217= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs376365012; called by muse, mutect2, varscan2
- ZNF622 | c.594C>T p.S198= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV58074309; called by muse, mutect2, varscan2
- ZNHIT3 | c.168T>G p.A56= | Silent (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 12/30 reads (40%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- BRD9 | c.401-15del | Intron (DEL) | VAF 12/36 reads (33%) | catalogued as rs747777302, COSV51319227; called by mutect2, varscan2
- BRSK2 | c.1939+277del | Intron (DEL) | VAF 11/42 reads (26%) | catalogued as rs751872197, COSV100373197; called by mutect2, varscan2
- CDHR5 | c.1379-9del | Intron (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- CTBP2 | c.59-2107del | Intron (DEL) | VAF 23/50 reads (46%) | called by mutect2, pindel, varscan2
- FAM153CP | chr5:178055953 G>A | 3'Flank (SNP) | VAF 23/66 reads (35%) | catalogued as rs766235123; called by muse, mutect2, varscan2
- MFSD4B | c.*186del | 3'UTR (DEL) | VAF 17/51 reads (33%) | catalogued as rs540972233; called by mutect2, varscan2
- PAX6 | c.142-108T>C | Intron (SNP) | VAF 25/68 reads (37%) | catalogued as COSV99570774; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.670A>G | RNA (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-3085G>A | Intron (SNP) | VAF 15/44 reads (34%) | catalogued as rs555610555, COSV100390127; called by muse, mutect2, varscan2
- SSPOP | n.3730del | RNA (DEL) | VAF 35/80 reads (44%) | catalogued as rs754581521; called by mutect2, pindel, varscan2
- SSPOP | n.4679G>A | RNA (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100022947; called by muse, mutect2, varscan2
- TK1 | chr17:78187094 C>T | 5'Flank (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100015095; called by muse, mutect2, varscan2
- USP42 | c.442+1316C>T | Intron (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
